HCMI case HCM-BROD-0332-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f0c1dd21-a156-4284-afda-985cd2656a9f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1962; Vital status: Alive.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 45.0 years (16,451 days); AJCC staging edition: 8th; AJCC pathologic T: T1b; AJCC pathologic N: N1b; AJCC pathologic stage: Stage IIIC; Prior malignancy: yes; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 55 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/6; ICD-10 code: C77.3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Classification of tumor: metastasis; Age at diagnosis: 53.5 years (19,556 days); Days to diagnosis: 3,105 days (8.5 years); Satellite nodule present: Absent.
   Pathology details: Breslow thickness category: <=1 mm; Lymph nodes positive: 1; Lymph nodes tested: 29; Lymphatic invasion present: No; Vascular invasion present: No.

Follow-up (2 entries)
- Days to follow up: 4,415 days (12.1 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 3,786.

Molecular and laboratory tests
- BRAF mutation, nos: Positive; Amino-acid change: V600E.
- NRAS mutation, nos: Negative.
- TP53 mutation, nos: Positive; Amino-acid change: Single copy deletion of TP53 at 17p13.1.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 83 kg; Height: 170 cm; BMI: 28.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Melanoma.

Biospecimens (2 samples)
- Sample HCM-BROD-0332-C43-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample HCM-BROD-0332-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 12.
